Somatic mutation profile of tumor specimen C3L-03372-04 (aliquot CPT0275960006) from CPTAC case C3L-03372, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 31.6 years (11,529 days).
Specimen C3L-03372-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5eaa1df-a01e-45ac-ac98-c58ca40f93e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03372-31 (Blood Derived Normal), aliquot CPT0265940002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db146b8b-dc0a-4802-b288-14dbe7736bbd

The open-access MAF lists 55 somatic variants for this specimen: 31 protein-altering or splice-affecting, 17 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 17, RNA 4, 5'UTR 2, Intron 1, Splice Region 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 52/201 reads (26%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.641A>G p.H214R | Missense Mutation (SNP) | VAF 206/400 reads (52%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs1057519992, CM103210, COSV52670202, COSV52732998, COSV52834506, COSV52887765; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- APLP2 | c.1205G>A p.R402H | Missense Mutation (SNP) | VAF 46/262 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as rs778175330; called by muse, mutect2, varscan2
- ATP10A | c.2426G>A p.R809H | Missense Mutation (SNP) | VAF 98/235 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776829827, COSV63516508, COSV63516647, COSV63518546; called by muse, mutect2, varscan2
- BEGAIN | c.-14C>T | Splice Region (SNP) | VAF 108/208 reads (52%) | catalogued as rs1231022593; called by muse, mutect2, varscan2
- CD1E | c.99G>T p.E33D | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as COSV63773068; called by muse, mutect2, varscan2
- HNMT | c.501G>C p.K167N | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV54506990; called by muse, mutect2, varscan2
- HPD | c.550A>G p.I184V | Missense Mutation (SNP) | VAF 137/817 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs767560456; called by muse, mutect2, varscan2
- HSPG2 | c.8245G>A p.V2749M | Missense Mutation (SNP) | VAF 203/431 reads (47%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.716); catalogued as rs755573009, COSV65969615; called by muse, mutect2, varscan2
- ITIH4 | c.2401G>A p.V801M | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs367925711; called by muse, mutect2, varscan2
- MROH5 | c.1001C>T p.A334V | Missense Mutation (SNP) | VAF 54/319 reads (17%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.927); catalogued as rs566254404; called by muse, mutect2, varscan2
- SLC12A2 | c.881G>A p.R294H | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1484832467; called by muse, mutect2, varscan2
- STXBP5L | c.1217A>G p.D406G | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752105786; called by muse, mutect2, varscan2
- TRARG1 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.229); catalogued as rs370410748, COSV61563388; called by muse, mutect2, varscan2
- APC2 | c.5005G>A p.G1669S | Missense Mutation (SNP) | VAF 91/349 reads (26%) | SIFT tolerated (0.79); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CLIP4 | c.727A>T p.T243S | Missense Mutation (SNP) | VAF 132/378 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTNAP2 | c.1734C>G p.C578W | Missense Mutation (SNP) | VAF 52/211 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DMP1 | c.1151G>C p.S384T | Missense Mutation (SNP) | VAF 123/245 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- EGR4 | c.770T>C p.F257S (on ENST00000545030; = p.F154S on NM_001965.4) | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- FOXK1 | c.31C>G p.R11G | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- GBX1 | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 52/338 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- KIAA0100 | c.256G>T p.V86L | Missense Mutation (SNP) | VAF 68/151 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KIF13B | c.5164C>A p.P1722T | Missense Mutation (SNP) | VAF 277/696 reads (40%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- NAT8 | c.540C>G p.I180M | Missense Mutation (SNP) | VAF 112/197 reads (57%) | SIFT tolerated (0.16); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- NPTX2 | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 107/239 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- NT5E | c.802A>G p.T268A | Missense Mutation (SNP) | VAF 173/342 reads (51%) | SIFT tolerated (0.73); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- P2RX4 | c.614T>C p.I205T | Missense Mutation (SNP) | VAF 61/215 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SGCE | c.475G>T p.V159L (on ENST00000647096; = p.V123L on NM_003919.3) | Missense Mutation (SNP) | VAF 54/151 reads (36%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- SLIT3 | c.3077A>T p.Y1026F | Missense Mutation (SNP) | VAF 76/150 reads (51%) | SIFT tolerated (0.3); PolyPhen benign (0.116); called by muse, varscan2
- SOX9 | c.21C>A p.F7L | Missense Mutation (SNP) | VAF 55/143 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- TP53 | c.1023_1031dup p.R342_L344dup | In Frame Ins (INS) | VAF 102/320 reads (32%) | called by mutect2, varscan2
- CSRNP2 | c.1116C>T p.C372= | Silent (SNP) | VAF 32/92 reads (35%) | catalogued as rs145581749, COSV50399125; called by muse, mutect2, varscan2
- CYP2C18 | c.558A>T p.R186= | Silent (SNP) | VAF 59/179 reads (33%) | called by muse, mutect2, varscan2
- GDF15 | c.354C>T p.S118= | Silent (SNP) | VAF 227/667 reads (34%) | called by muse, mutect2, varscan2
- GPR12 | c.297C>T p.T99= | Silent (SNP) | VAF 18/206 reads (9%) | called by muse, mutect2
- KDM2B | c.1212G>A p.S404= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as rs781871295; called by muse, mutect2, varscan2
- KEAP1 | c.1732C>T p.L578= | Silent (SNP) | VAF 88/203 reads (43%) | called by muse, mutect2, varscan2
- MON2 | c.2157C>T p.G719= | Silent (SNP) | VAF 49/261 reads (19%) | catalogued as rs758615154, COSV54813239; called by muse, mutect2, varscan2
- NFATC1 | c.2541C>A p.P847= (on ENST00000427363 / NM_001278669.2; = p.P834= on NM_172387.3) | Silent (SNP) | VAF 10/124 reads (8%) | called by muse, mutect2
- NLRC3 | c.1698C>T p.N566= | Silent (SNP) | VAF 95/322 reads (30%) | catalogued as rs368211460; called by muse, mutect2, varscan2
- OR52N1 | c.702T>C p.D234= | Silent (SNP) | VAF 47/299 reads (16%) | called by muse, mutect2, varscan2
- OR6C65 | c.639T>C p.V213= | Silent (SNP) | VAF 54/171 reads (32%) | catalogued as COSV65568293; called by muse, mutect2, varscan2
- SLC22A18AS | c.234C>T p.G78= | Silent (SNP) | VAF 29/170 reads (17%) | called by muse, mutect2, varscan2
- TARM1 | c.66C>T p.C22= (on ENST00000616041 / NM_001330650.1; = p.C14= on NM_001135686.3) | Silent (SNP) | VAF 79/262 reads (30%) | catalogued as rs899888207, COSV71524872; called by muse, mutect2, varscan2
- TGM6 | c.687C>T p.N229= | Silent (SNP) | VAF 196/479 reads (41%) | catalogued as rs370489062; ClinVar: likely benign; called by muse, mutect2, varscan2
- VWA8 | c.4035A>G p.L1345= | Silent (SNP) | VAF 39/80 reads (49%) | catalogued as rs754852047; called by muse, mutect2, varscan2
- ZDBF2 | c.4773C>A p.P1591= | Silent (SNP) | VAF 15/110 reads (14%) | called by muse, mutect2, varscan2
- ZNF724 | c.834A>G p.G278= | Silent (SNP) | VAF 19/42 reads (45%) | called by muse, mutect2, varscan2
- AC024940.1 | n.5192C>A | RNA (SNP) | VAF 63/234 reads (27%) | called by muse, mutect2, varscan2
- AC079154.1 | n.987A>G | RNA (SNP) | VAF 47/128 reads (37%) | called by muse, mutect2, varscan2
- C1R | c.-3A>T | 5'UTR (SNP) | VAF 64/487 reads (13%) | called by muse, mutect2, varscan2
- C9orf85 | c.323+1153G>T | Intron (SNP) | VAF 7/34 reads (21%) | catalogued as COSV58255048; called by muse, mutect2, varscan2
- DHRS7B | c.-41T>G | 5'UTR (SNP) | VAF 84/226 reads (37%) | catalogued as rs375926496; called by muse, mutect2, varscan2
- SRRM2-AS1 | n.331C>T | RNA (SNP) | VAF 48/536 reads (9%) | catalogued as rs145280095; called by muse, mutect2
- UGT2B27P | n.1552T>C | RNA (SNP) | VAF 119/292 reads (41%) | catalogued as rs770772288; called by muse, mutect2, varscan2
